FM case AD3456 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/3c729364-23b7-4f2a-83f4-4087bcf47630

Male, 46.9 years: Pituitary adenoma, NOS (ICD-O-3 8272/0) of the pituitary gland; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
